Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHD, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAHD-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 4.0 cm; no invasion in rete testis; no angio-invasion.
The cord is not involved, including the resection margin..

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD-O-3
Seminoma NOS 9061/3
Site: Rete testis NOS C62.9
JW 3/7/14

Source: NCI Genomic Data Commons file fb316337-eb9d-421c-b2d5-46fe47705066 (TCGA-2G-AAHD-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).